Somatic mutation profile of tumor specimen TCGA-PN-A8MA-01A (aliquot TCGA-PN-A8MA-01A-11D-A36J-09) from TCGA case TCGA-PN-A8MA, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 43.6 years (15,918 days).
Specimen TCGA-PN-A8MA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 559f9d90-77f1-4c67-a95f-c9f1145a250e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-PN-A8MA-10A (Blood Derived Normal), aliquot TCGA-PN-A8MA-10A-01D-A36M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/00a963bf-2a4b-448d-af0a-4dae5060fa4e

The open-access MAF lists 157 somatic variants for this specimen: 117 protein-altering or splice-affecting, 39 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 103, Silent 39, Nonsense Mutation 9, Splice Site 2, Splice Region 1, 5'Flank 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 46/94 reads (49%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCG2 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as CM068172, COSV99419001; called by muse, mutect2, varscan2
- ACLY | c.2744G>A p.R915Q | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100709624; called by muse, mutect2, varscan2
- ALMS1 | c.6674C>T p.S2225F | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100041942; called by muse, varscan2
- AP2A1 | c.566C>T p.T189M | Missense Mutation (SNP) | VAF 13/147 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs762300764, COSV100756046; called by muse, mutect2
- APEH | c.2131G>C p.E711Q | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.062); catalogued as COSV99610693; called by muse, mutect2, varscan2
- ATP10A | c.3357C>A p.D1119E | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.893); catalogued as COSV100791071, COSV100791599; called by muse, mutect2, varscan2
- ATP2A1 | c.420C>G p.I140M | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV100837235; called by muse, mutect2, varscan2
- ATRX | c.7355A>G p.Q2452R | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.444); catalogued as COSV100970493, COSV64875319; called by muse, mutect2, varscan2
- BAIAP2L1 | c.127G>A p.A43T | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.116); catalogued as rs202012767, COSV50055251, COSV99134200; called by mutect2, varscan2
- BLMH | c.834C>G p.H278Q | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as COSV99913087; called by muse, mutect2, varscan2
- BRINP3 | c.760C>A p.R254S | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV66539622; called by muse, mutect2, varscan2
- C21orf58 | c.128C>G p.P43R | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.758); catalogued as COSV52448877, COSV99387979; called by muse, mutect2, varscan2
- CA11 | c.250C>G p.L84V | Missense Mutation (SNP) | VAF 52/73 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.46); catalogued as COSV99320581; called by muse, mutect2, varscan2
- CACNA1G | c.6148G>C p.D2050H | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as COSV100661612; called by muse, mutect2, varscan2
- CASZ1 | c.5089G>A p.D1697N | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.134); catalogued as COSV100985218; called by muse, mutect2
- CELSR3 | c.2501C>T p.S834F | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99373186, COSV99373408; called by muse, mutect2, varscan2
- CHEK2 | c.1248G>C p.K416N (on ENST00000382580 / NM_001005735.2; = p.K373N on NM_007194.4) | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); catalogued as COSV100101427; called by muse, mutect2
- CLSTN2 | c.2236G>C p.E746Q | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.915); catalogued as COSV101515640; called by muse, mutect2, varscan2
- CRYM | c.823G>A p.V275M | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs1224591120, COSV99561689; called by muse, mutect2, varscan2
- CSDE1 | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs1171140426, COSV99794590; called by muse, mutect2
- CUX1 | c.3002G>A p.R1001Q | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99471090; called by muse, mutect2, varscan2
- DDX46 | c.770C>G p.S257C | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.408); catalogued as COSV100844864; called by muse, mutect2, varscan2
- DHX57 | c.3731G>C p.R1244T | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.396); catalogued as COSV99769323; called by muse, mutect2, varscan2
- DNAH17 | c.4213G>A p.V1405M | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.183); catalogued as rs202202365; called by muse, mutect2, varscan2
- DST | c.14761G>C p.E4921Q (on ENST00000361203 / NM_001374722.1; = p.E2509Q on NM_015548.5) | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV99753985; called by muse, mutect2, varscan2
- E2F2 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); catalogued as COSV62276782; called by muse, mutect2, varscan2
- EEF2K | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.055); catalogued as rs1175366642, COSV99532934; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.2327G>A p.R776H | Missense Mutation (SNP) | VAF 31/260 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs780759837, COSV100348982; called by muse, mutect2, varscan2
- EPHA3 | c.2667G>T p.K889N | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV100341795, COSV60713346, COSV60728845; called by muse, mutect2, varscan2
- EQTN | c.540C>G p.I180M | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.349); catalogued as rs1304004514, COSV101192494; called by muse, mutect2, varscan2
- FAM187B | c.50G>A p.G17E | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.207); catalogued as rs1245612519, COSV100219981; called by muse, mutect2, varscan2
- FHOD3 | c.816G>A p.T272= | Splice Region (SNP) | VAF 9/31 reads (29%) | catalogued as rs1371010151, COSV99940797; called by muse, mutect2, varscan2
- FKRP | c.1437G>C p.E479D | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100586670; called by muse, mutect2, varscan2
- FLG | c.10204C>T p.R3402W | Missense Mutation (SNP) | VAF 53/159 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.087); catalogued as rs141655789; called by muse, mutect2, varscan2
- FSIP1 | c.1286G>C p.R429T | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.053); catalogued as COSV100618034, COSV100618120; called by muse, mutect2, varscan2
- GAS6 | c.1534C>G p.H512D | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.043); catalogued as COSV100581352; called by muse, mutect2, varscan2
- GINS3 | c.412C>G p.L138V | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.6); catalogued as COSV100139262; called by muse, mutect2, varscan2
- GPR50 | c.1726G>T p.A576S | Missense Mutation (SNP) | VAF 30/44 reads (68%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.011); catalogued as COSV99505917; called by muse, mutect2, varscan2
- HEATR5A | c.1195G>A p.V399I | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.013); catalogued as rs372569181; called by muse, mutect2, varscan2
- HECW1 | c.3694C>T p.R1232C | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs771124413, COSV67835802; called by muse, mutect2, varscan2
- HERC5 | c.1879G>A p.V627I | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.266); catalogued as rs148569726; called by muse, mutect2, varscan2
- HOOK1 | c.672G>A p.M224I | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV100969037; called by muse, mutect2, varscan2
- HYDIN | c.547G>C p.E183Q | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as rs1248952330, COSV99862643; called by muse, mutect2, varscan2
- IGFBP5 | c.337G>C p.E113Q | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.29); catalogued as COSV99288877; called by muse, mutect2, varscan2
- IGSF8 | c.1538G>C p.G513A | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT tolerated (0.51); PolyPhen benign (0.164); catalogued as COSV100081606; called by muse, mutect2, varscan2
- IL3RA | c.424G>A p.V142I | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as rs1253339354, COSV100452243; called by muse, mutect2, varscan2
- KAT14 | c.1528G>A p.D510N | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.28); catalogued as rs1401519936, COSV100890052; called by muse, mutect2, varscan2
- KCNB2 | c.436G>C p.E146Q | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101578618, COSV101578724; called by muse, varscan2
- KDM3B | c.2344G>A p.D782N | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.031); catalogued as rs1030476722, COSV58691360; called by muse, mutect2, varscan2
- KDM6A | c.2165G>T p.G722V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV100938053; called by muse, varscan2
- KDM6A | c.2434G>T p.D812Y | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); catalogued as COSV100938054; called by muse, mutect2, varscan2
- KIAA0753 | c.958C>T p.Q320* | Nonsense Mutation (SNP) | VAF 8/34 reads (24%) | catalogued as rs775543251, COSV100810561, COSV63819110; called by muse, mutect2, varscan2
- KLHL36 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.664); catalogued as rs1297825479, COSV99256684; called by muse, mutect2, varscan2
- KRT40 | c.865C>T p.Q289* | Nonsense Mutation (SNP) | VAF 5/15 reads (33%) | catalogued as COSV100898823; called by muse, mutect2, varscan2
- LIMK1 | c.1563C>G p.I521M | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0.323); catalogued as COSV100283102; called by muse, mutect2, varscan2
- LIN28B | c.536G>C p.R179T | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); catalogued as COSV100558694; called by muse, mutect2, varscan2
- MANBA | c.2300G>A p.R767K (on ENST00000642252; = p.R721K on NM_005908.4) | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.82); PolyPhen benign (0.026); catalogued as COSV99898555; called by muse, mutect2, varscan2
- MDN1 | c.7718C>T p.S2573L | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as COSV101021072; called by muse, varscan2
- MMGT1 | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as COSV100018464; called by muse, mutect2, varscan2
- MRPL22 | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV99501629; called by muse, mutect2, varscan2
- MTR | c.1771C>T p.R591* | Nonsense Mutation (SNP) | VAF 17/106 reads (16%) | catalogued as rs777459947, COSV100855324; called by muse, mutect2, varscan2
- MYH1 | c.476C>G p.S159C | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV56848377, COSV99875499; called by muse, mutect2, varscan2
- MYO16 | c.1081G>C p.D361H | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV51779842, COSV99193783; called by muse, mutect2, varscan2
- NID2 | c.1760G>C p.G587A | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53498887, COSV99356276; called by muse, mutect2, varscan2
- NLGN4X | c.1425C>G p.H475Q | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.928); catalogued as COSV99321058; called by muse, mutect2, varscan2
- NLRP8 | c.752C>T p.T251M | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.053); catalogued as rs764375811, COSV52585164; called by muse, mutect2, varscan2
- NME8 | c.95T>C p.I32T | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs200758390, COSV99553094; called by muse, mutect2, varscan2
- NPTX1 | c.1084C>G p.L362V | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.998); catalogued as COSV100150957; called by muse, mutect2, varscan2
- NUP155 | c.2941G>A p.E981K (on ENST00000231498 / NM_153485.3; = p.E922K on NM_004298.4) | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.115); catalogued as COSV99192569; called by muse, mutect2, varscan2
- OFD1 | c.1660G>A p.E554K | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV100406844; called by muse, mutect2, varscan2
- OLIG1 | c.811A>C p.K271Q | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as COSV100287147; called by muse, mutect2
- PDIA4 | c.481G>C p.V161L | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV99618427; called by muse, mutect2, varscan2
- PEG10 | c.475G>A p.E159K (on ENST00000482108 / NM_001040152.2; = p.E193K on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.868); catalogued as COSV101509878; called by muse, mutect2, varscan2
- PKLR | c.1125G>T p.E375D | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as COSV100712867; called by muse, mutect2, varscan2
- POU4F2 | c.992G>A p.R331H | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs867084774, COSV55582937; called by muse, mutect2, varscan2
- PRDM7 | c.948G>A p.M316I | Missense Mutation (SNP) | VAF 29/208 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as rs1462832607, COSV100371118; called by muse, mutect2, varscan2
- PRKCZ | c.1765G>A p.E589K | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs779910797, COSV100423129, COSV100423131; called by muse, mutect2, varscan2
- PRX | c.2476G>A p.E826K | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.352); catalogued as COSV99397622; called by muse, mutect2
- PTDSS1 | c.304C>T p.R102* | Nonsense Mutation (SNP) | VAF 10/48 reads (21%) | catalogued as COSV100428586; called by muse, mutect2, varscan2
- RARS1 | c.219G>A p.M73I | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV99199078; called by muse, mutect2, varscan2
- RASAL2 | c.3268G>A p.V1090M | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.298); catalogued as rs371002131; called by muse, mutect2, varscan2
- REC8 | c.865-1G>A p.X289_splice | Splice Site (SNP) | VAF 33/159 reads (21%) | catalogued as COSV100268953, COSV61018374; called by muse, mutect2, varscan2
- RIMBP2 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 76/163 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as rs771459544, COSV99899018; called by muse, mutect2, varscan2
- ROBO1 | c.3709C>T p.R1237* | Nonsense Mutation (SNP) | VAF 7/10 reads (70%) | catalogued as rs553326251, COSV101458322; called by muse, varscan2
- RRBP1 | c.3414+1G>A p.X1138_splice (on ENST00000377813 / NM_001365613.2; = p.X705_splice on NM_004587.3) | Splice Site (SNP) | VAF 23/76 reads (30%) | catalogued as COSV99853794; called by muse, mutect2, varscan2
- RTTN | c.2182G>A p.D728N | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs375149092; called by muse, mutect2, varscan2
- SERPINB7 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.241); catalogued as rs756029823, COSV100320421, COSV60534448; called by muse, mutect2, varscan2
- SIGLEC5 | c.1394G>A p.R465H | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.818); catalogued as rs757275164, COSV55778499; called by muse, mutect2, varscan2
- SLC25A12 | c.1561C>T p.L521F | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99784854; called by muse, varscan2
- SLC39A14 | c.125C>T p.S42F | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV99249691; called by muse, mutect2, varscan2
- SLITRK1 | c.736A>T p.R246* | Nonsense Mutation (SNP) | VAF 20/79 reads (25%) | catalogued as COSV100999889; called by muse, mutect2, varscan2
- SLITRK4 | c.365T>C p.L122P | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100567262; called by muse, varscan2
- SMG1 | c.3931C>T p.Q1311* | Nonsense Mutation (SNP) | VAF 72/555 reads (13%) | catalogued as COSV101245596, COSV67171292; called by muse, mutect2, varscan2
- SNCAIP | c.2014C>G p.Q672E | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV99748133; called by muse, mutect2, varscan2
- SZT2 | c.8140C>T p.R2714* (on ENST00000634258 / NM_001365999.1; = p.R2657* on NM_015284.4) | Nonsense Mutation (SNP) | VAF 14/50 reads (28%) | catalogued as rs1438773569, COSV65168432; called by muse, mutect2, varscan2
- TGS1 | c.2162A>G p.D721G | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99485244; called by muse, mutect2, varscan2
- TMCO4 | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs376327918; called by muse, mutect2, varscan2
- TNPO1 | c.1799C>T p.S600L | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV100473254; called by muse, mutect2
- TRIO | c.6509T>G p.F2170C | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV100710192; called by muse, mutect2
- TXK | c.656A>T p.H219L | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as COSV99972343; called by muse, mutect2, varscan2
- TYR | c.149C>T p.S50L | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs61753181, CM056074, CM135750, CM941343, COSV99633845; called by muse, mutect2, varscan2
- UBXN4 | c.719G>C p.R240T | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.522); catalogued as COSV99738909; called by muse, mutect2, varscan2
- USP12 | c.969G>C p.K323N | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99997513; called by muse, mutect2, varscan2
- ZFP28 | c.1022C>T p.S341F | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.078); catalogued as COSV100019451; called by muse, mutect2, varscan2
- ZKSCAN2 | c.2440G>T p.D814Y | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100047984; called by muse, mutect2, varscan2
- ZNF236 | c.538G>T p.V180L | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV99470011; called by muse, mutect2, varscan2
- ZNF28 | c.460T>G p.F154V | Missense Mutation (SNP) | VAF 19/244 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.242); catalogued as COSV100354407; called by muse, mutect2
- ZNF335 | c.3341G>A p.R1114H | Missense Mutation (SNP) | VAF 19/310 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs757219780, COSV100532847; called by muse, mutect2
- ZNF419 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 51/77 reads (66%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as rs748322156, COSV99691980; called by muse, mutect2, varscan2
- ZNF423 | c.1273C>T p.R425W (on ENST00000563137 / NM_001379286.1; = p.R417W on NM_015069.4) | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as rs772823132, COSV52197113; called by muse, mutect2, varscan2
- ZNF689 | c.959C>T p.P320L | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.999); catalogued as rs758801900, COSV99787937; called by muse, mutect2, varscan2
- ZNF75D | c.1503_1505del p.R502del | In Frame Del (DEL) | VAF 10/36 reads (28%) | catalogued as rs1273316595; called by pindel, varscan2
- ZNF813 | c.343G>T p.E115* | Nonsense Mutation (SNP) | VAF 22/198 reads (11%) | catalogued as COSV101124763, COSV67176702; called by muse, varscan2
- ZNF835 | c.986C>G p.T329R | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV101606315; called by muse, mutect2
- ZZZ3 | c.1423C>G p.Q475E | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV66234843; called by muse, mutect2
- MID1 | c.919dup p.E307Gfs*18 | Frame Shift Ins (INS) | VAF 13/50 reads (26%) | called by mutect2, pindel, varscan2
- ACP7 | c.489C>T p.D163= | Silent (SNP) | VAF 6/67 reads (9%) | catalogued as COSV58698776; called by muse, mutect2
- ADCY7 | c.2028C>T p.I676= | Silent (SNP) | VAF 18/81 reads (22%) | catalogued as rs774567030, COSV99575854; called by muse, mutect2, varscan2
- ATP13A2 | c.2511C>T p.F837= | Silent (SNP) | VAF 32/200 reads (16%) | catalogued as rs1324223115, COSV100454035; called by muse, mutect2, varscan2
- BMP15 | c.792G>A p.R264= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV99399330; called by muse, mutect2, varscan2
- CCR10 | c.648C>T p.F216= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs955181145, COSV99226245; called by muse, mutect2
- DMC1 | c.129A>T p.V43= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as COSV99319254; called by muse, mutect2, varscan2
- EPB41L4A | c.801C>T p.N267= | Silent (SNP) | VAF 16/65 reads (25%) | catalogued as rs771415842, COSV54873342; called by muse, mutect2, varscan2
- ERCC2 | c.2259A>C p.I753= | Silent (SNP) | VAF 9/51 reads (18%) | called by muse, varscan2
- FCRL4 | c.1413G>T p.L471= | Silent (SNP) | VAF 22/74 reads (30%) | catalogued as COSV54867272; called by muse, mutect2, varscan2
- GUSB | c.1224C>T p.P408= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as rs757418833, COSV100512569; called by muse, mutect2, varscan2
- KCNB2 | c.552G>A p.E184= | Silent (SNP) | VAF 24/76 reads (32%) | catalogued as rs1408962317, COSV73049374, COSV73050465; called by muse, varscan2
- KDM6A | c.2088C>A p.L696= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV100938052; called by muse, varscan2
- KIF13B | c.240C>T p.F80= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as COSV101580580; called by muse, mutect2, varscan2
- MB21D2 | c.723C>T p.F241= | Silent (SNP) | VAF 33/68 reads (49%) | catalogued as COSV101165070; called by muse, mutect2, varscan2
- MFNG | c.681C>T p.I227= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV100812876; called by muse, mutect2, varscan2
- NEUROD1 | c.72C>T p.D24= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as rs1284838712, COSV54548790; called by muse, mutect2, varscan2
- OR2H2 | c.717C>T p.C239= | Silent (SNP) | VAF 50/74 reads (68%) | catalogued as COSV100589592; called by muse, mutect2, varscan2
- PCDH17 | c.2358G>A p.V786= | Silent (SNP) | VAF 36/133 reads (27%) | catalogued as COSV100931555; called by muse, mutect2, varscan2
- PCDHA6 | c.1509G>A p.A503= | Silent (SNP) | VAF 24/106 reads (23%) | catalogued as rs782636374, COSV100971740, COSV65343482; called by muse, mutect2, varscan2
- PFKM | c.360C>T p.G120= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as rs886049453, COSV100402392; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PSG8 | c.96G>A p.T32= | Silent (SNP) | VAF 33/316 reads (10%) | catalogued as rs370832692; called by muse, mutect2, varscan2
- PTPN21 | c.2289C>T p.H763= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as COSV100161763; called by muse, mutect2, varscan2
- RABEP2 | c.201G>A p.T67= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as rs1162507283, COSV100706935; called by muse, mutect2, varscan2
- RASA3 | c.234C>T p.F78= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as COSV61873427; called by muse, mutect2, varscan2
- RBMXL2 | c.822G>C p.L274= | Silent (SNP) | VAF 21/95 reads (22%) | catalogued as COSV100182178; called by muse, mutect2, varscan2
- RBMXL2 | c.1011G>A p.S337= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as COSV100182180; called by muse, mutect2, varscan2
- REEP2 | c.207G>A p.K69= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV99649563; called by muse, mutect2, varscan2
- SCGB1D2 | c.102C>T p.F34= | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as rs189227523, COSV99793547; called by muse, mutect2, varscan2
- SERPINB2 | c.330C>T p.L110= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as COSV100208325; called by muse, mutect2, varscan2
- SERPIND1 | c.1281C>T p.I427= | Silent (SNP) | VAF 19/129 reads (15%) | catalogued as COSV99300133; called by muse, mutect2, varscan2
- SLC22A13 | c.84C>T p.L28= | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as COSV61290918; called by muse, mutect2, varscan2
- SLC26A3 | c.1524C>T p.C508= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as COSV100384978; called by muse, mutect2, varscan2
- STK11IP | c.3240C>T p.I1080= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV99822633; called by muse, mutect2, varscan2
- SYNE1 | c.19477C>T p.L6493= (on ENST00000367255 / NM_182961.4; = p.L6422= on NM_033071.3) | Silent (SNP) | VAF 32/68 reads (47%) | catalogued as COSV55014295, COSV99559366; called by muse, mutect2, varscan2
- TBX2 | c.729G>A p.L243= | Silent (SNP) | VAF 45/113 reads (40%) | catalogued as COSV99538773; called by muse, mutect2, varscan2
- TGIF1 | c.300G>A p.T100= (on ENST00000330513 / NM_001374396.1; = p.T120= on NM_003244.4) | Silent (SNP) | VAF 18/103 reads (17%) | catalogued as rs767183444, COSV100394787; called by muse, mutect2, varscan2
- THOC2 | c.2781G>A p.E927= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV99833083; called by muse, mutect2, varscan2
- TLE5 | c.507G>T p.L169= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV99682277; called by muse, mutect2, varscan2
- TSKS | c.516C>T p.S172= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as rs1354890359, COSV55873127; called by muse, mutect2, varscan2
- ZNF578 | chr19:52451276 del TT | 5'Flank (DEL) | VAF 20/198 reads (10%) | called by mutect2, pindel
